Somatic mutation profile of tumor specimen 0DBNBE from CCDI case PBBKZT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.5 years (5,678 days).
Specimen 0DBNBE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0674b791-453f-4995-9b52-40dba7fb5b4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBNBM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4024cdca-6d10-41c7-90ee-a6b468a0e92d

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH10 | c.1559G>A p.R520Q (on ENST00000409039; = p.R459Q on NM_207437.3) | Missense Mutation (SNP) | VAF 101/597 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs766869862, COSV69001179; called by muse, mutect2, varscan2
- SLC6A19 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 81/760 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs1344159365, COSV100443706; called by muse, mutect2, varscan2
- AGAP3 | c.1090G>A p.G364S (on ENST00000622464; = p.G400S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/426 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- BRWD3 | c.3500C>T p.A1167V | Missense Mutation (SNP) | VAF 26/545 reads (5%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.449); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 37/968 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- F13A1 | c.1978A>G p.T660A | Missense Mutation (SNP) | VAF 26/968 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- MATK | c.1090C>G p.L364V (on ENST00000310132 / NM_139355.3; = p.L365V on NM_002378.4) | Missense Mutation (SNP) | VAF 104/625 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SLC6A7 | c.1762A>G p.T588A | Missense Mutation (SNP) | VAF 81/555 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SMG6 | c.2187G>A p.M729I | Missense Mutation (SNP) | VAF 103/673 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CPEB2 | c.516G>A p.Q172= | Silent (SNP) | VAF 67/569 reads (12%) | catalogued as rs1400605873; called by muse, mutect2, varscan2
- PPP2R2C | c.513C>T p.G171= | Silent (SNP) | VAF 87/562 reads (15%) | called by muse, mutect2, varscan2
- RTP2 | c.441C>T p.S147= | Silent (SNP) | VAF 101/555 reads (18%) | catalogued as COSV64079087; called by muse, mutect2, varscan2
- SLC17A7 | c.1482G>A p.K494= | Silent (SNP) | VAF 89/576 reads (15%) | called by muse, mutect2, varscan2
- CD99 | c.149-91G>A | Intron (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.471+29C>G | Intron (SNP) | VAF 14/416 reads (3%) | called by muse, mutect2
- FGFR1 | c.1082-21_1082-20insT | Intron (INS) | VAF 144/744 reads (19%) | called by mutect2, varscan2
